Somatic mutation profile of tumor specimen C3N-00733-01 (aliquot CPT0025880009) from CPTAC case C3N-00733, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 56.1 years (20,507 days).
Specimen C3N-00733-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ed58339-91ec-4d86-ad7c-1f64f34f3d10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00733-31 (Blood Derived Normal), aliquot CPT0028480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb8f2ac4-f0c6-4a9d-8e97-7adabaeb55a8

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 7, Frame Shift Del 2, Intron 2, Splice Site 2, RNA 2, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.340+1G>T p.X114_splice | Splice Site (SNP) | VAF 47/209 reads (22%) | hotspot (GDC flag); catalogued as rs730882032, CS044968, CS982396, COSV56543763, COSV56544858, COSV56545042, COSV56546938; called by muse, mutect2, varscan2
- ADAMTS12 | c.4174G>A p.V1392M | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs777630888, COSV100711434, COSV61275688; called by muse, mutect2, varscan2
- CDA | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV66751646; called by muse, mutect2, varscan2
- CRACD | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 47/327 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs761571893, COSV51721568, COSV51729215; called by muse, mutect2, varscan2
- HMCN1 | c.8596C>A p.L2866I | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99629176; called by muse, mutect2
- IRX4 | c.849C>A p.D283E | Missense Mutation (SNP) | VAF 159/491 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99180752; called by muse, mutect2, varscan2
- KRTAP10-5 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 20/582 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1215319562; called by muse, mutect2
- LRFN4 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as rs773088818; called by muse, mutect2, varscan2
- PKD1 | c.9569G>A p.G3190E | Missense Mutation (SNP) | VAF 130/911 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM158591; called by muse, mutect2, varscan2
- ABCC2 | c.3615-6_3631del p.X1205_splice | Splice Site (DEL) | VAF 70/566 reads (12%) | called by mutect2, pindel
- BRI3BP | c.119G>C p.G40A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- C19orf25 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCNO | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- CHP2 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- CLPB | c.595T>A p.F199I | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CPD | c.1595C>A p.S532* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- DNAH11 | c.13071_13075dup p.R4359Hfs*30 | Frame Shift Ins (INS) | VAF 48/189 reads (25%) | called by mutect2, pindel, varscan2
- DPP4 | c.2030A>T p.E677V | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DSPP | c.3197G>A p.S1066N | Missense Mutation (SNP) | VAF 134/851 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, varscan2
- DUSP9 | c.314del p.V105Gfs*79 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | called by mutect2, pindel, varscan2
- HECTD4 | c.11213_11230del p.R3738_P3743del | In Frame Del (DEL) | VAF 30/204 reads (15%) | called by mutect2, pindel
- HMCN1 | c.13735_13742del p.Q4579Afs*7 | Frame Shift Del (DEL) | VAF 92/628 reads (15%) | called by mutect2, pindel
- KMT2C | c.14279C>G p.S4760W | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP2 | c.2551A>G p.I851V | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- MAP3K1 | c.1081G>C p.V361L | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MAPK7 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC2 | c.1835A>G p.K612R | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NCAM2 | c.1551C>G p.N517K | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDUFAF4 | c.342T>G p.I114M | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PCDHA11 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 145/992 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RELCH | c.3497A>C p.K1166T | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- RTN4RL2 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SLC35A2 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLITRK3 | c.657C>A p.H219Q | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SORCS2 | c.2566A>T p.N856Y | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SPDYC | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- STIP1 | c.1492A>C p.I498L | Missense Mutation (SNP) | VAF 65/333 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SUFU | c.1352C>A p.T451N | Missense Mutation (SNP) | VAF 14/401 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRIM60 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC3 | c.1736A>T p.Y579F | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WNK3 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF611 | c.1398T>G p.S466R | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLUH | c.3177C>T p.P1059= (on ENST00000435359; = p.P1098= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- FERMT3 | c.294G>T p.R98= | Silent (SNP) | VAF 73/347 reads (21%) | called by muse, mutect2, varscan2
- PTCH1 | c.1257G>A p.V419= | Silent (SNP) | VAF 115/461 reads (25%) | catalogued as rs1060504535; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RGPD4 | c.4086A>T p.A1362= | Silent (SNP) | VAF 137/641 reads (21%) | called by muse, mutect2, varscan2
- RMC1 | c.1216C>T p.L406= | Silent (SNP) | VAF 50/278 reads (18%) | called by muse, mutect2, varscan2
- SPATA20 | c.2019G>A p.L673= (on ENST00000356488 / NM_001258372.1; = p.L689= on NM_022827.4) | Silent (SNP) | VAF 17/589 reads (3%) | called by muse, mutect2
- ZNF292 | c.6504T>G p.T2168= | Silent (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- CSF2RA | c.*145C>T | 3'UTR (SNP) | VAF 28/167 reads (17%) | catalogued as rs750257726, COSV100817396; called by muse, mutect2, varscan2
- GVINP1 | n.5046dup | RNA (INS) | VAF 40/256 reads (16%) | called by mutect2, pindel, varscan2
- HNF4A-AS1 | n.356+1330C>A | Intron (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- KRT17P1 | n.1073G>T | RNA (SNP) | VAF 76/1166 reads (7%) | called by muse, mutect2
- MEIS1 | c.1114+36G>A | Intron (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
